Surgical pathology report (de-identified scan), TCGA case TCGA-77-8007, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Prince Charles Hospital, specimen TCGA-77-8007-01A (Primary Tumor).

[page 1 of 2]
RIGHT UPPER LOBECTOMY

Clinical Details:

Right upper lobectomy for carcinoma of lung.
Patient has been exposed to asbestos.

Four specimens submitted:

1: RIGHT UPPER LOBE

Macroscopy:

The specimen consists of a lobectomy specimen measuring 170 x 70 mm with a depth of up to 80 mm. Some puckering is present over the lateral pleural surface. The tumour measures 75 x 55 x 75 mm and abuts, does not clearly penetrate, the pleural surface. The tumour appears at least 20 mm clear of the hilar resection margin. There is no obvious endophytic bronchial component to the tumour, although it clearly is associated with bronchial structures. A separate small pleural nodule is identified, 45 mm from the nearest tumour. [Bronchial resection margin, 1A; vascular resection margin, 1B; hilar lymph nodes, 1C-1G; block 1E includes inked resection margin; pleural surface with tumour, 1H-1I; tumour towards hilar aspect, 1J-1L; separate pleural nodule, 1M; macroscopically unremarkable lung, 1N].

Microscopy:

Sections show a poorly differentiated squamous cell carcinoma with extensive central necrosis and cavitation. A definite bronchial origin is not identified. There is no evidence of pleural invasion, and the separate pleural nodule is shown to represent a silicotic nodule within a pleural lymph node. No lymphatic invasion is seen, however metastatic carcinoma is present in one of the peribronchial lymph nodes. Vascular invasion is identified. The bronchial resection margin is clear of malignancy but shows a benign mucous gland adenoma. Lung parenchyma adjacent to the tumour shows organising pneumonia while distant lung parenchyma shows emphysema.

2: HILAR LYMPH NODE

Macroscopy:

The specimen consists of a piece of dark brown tissue, 4 x 4 x 3 mm. [BIT, 2A]

Microscopy:

Sections show fragments of lymph nodes containing large numbers of pigmented macrophages but showing no evidence of metastatic carcinoma.

3: PARTIAL BRONCHUS RIGHT SIDE

Macroscopy:

The specimen consists of a portion of bronchial wall measuring 25 x 15 x 5 mm. No obvious mucosal abnormality is identified. [Serially sectioned and all pieces blocked, 3A].

Microscopy:

Sections show full thickness bronchial wall in which there is no evidence of the mucous gland adenoma seen in the resection margin of specimen 1. However there is squamous metaplasia with severe dysplasia which falls short of carcinoma in situ. There is no evidence of invasive malignancy.

Conclusion:

Partial bronchus right side: squamous metaplasia with severe dysplasia.

4: MEDIASTINAL LYMPH NODE

Macroscopy:

The specimen consists of a lymph node measuring 8 x 6 x 3 mm with attached fatty tissue. [All tissue blocked, 4A].

Microscopy:

[page 2 of 2]
[REDACTED]

Sections show a lymph node containing numerous pigmented macrophages but showing no evidence of metastatic carcinoma.

Conclusion (Specimens 1,2 and 4):

Right upper lobectomy and lymph node sampling:

Poorly differentiated squamous cell carcinoma, 75 mm in diameter.

Vascular invasion is present.

Metastatic carcinoma in peribronchial lymph node.

No pleural invasion.

Mucous gland adenoma at bronchial resection margin.

Pathological stage T2 N1.

T-28000 M-80703 P1-03000

T-26000 M-74000 P1-03000

T-26000 M-81400 P1-03000

Reported by [REDACTED]
Pathology Registrar/Anatomical Pathologist

[REDACTED]

cc:

[REDACTED]

Source: NCI Genomic Data Commons file ad2c9109-7181-4e00-b47f-1dd162a80484 (TCGA-77-8007.AF0112BD-A19F-4DDC-9261-ACA3AFD9831C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).